CCDI case PBCHPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/1a1d1979-8b4e-412f-a154-78c677d1a2d1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 16.5 years (6,010 days).

Biospecimens (3 samples)
- Sample 0DSBXW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSBY6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSBYF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
